Somatic mutation profile of tumor specimen TCGA-04-1343-01A (aliquot TCGA-04-1343-01A-01W-0488-09) from TCGA case TCGA-04-1343, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 72.4 years (26,428 days).
Specimen TCGA-04-1343-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 765c93af-4c97-43eb-a766-53631324f8d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1343-10A (Blood Derived Normal), aliquot TCGA-04-1343-10A-01W-0487-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60ed5ac1-d754-4ac0-a175-71c678a67c4f

The open-access MAF lists 91 somatic variants for this specimen: 56 protein-altering or splice-affecting, 34 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 34, Nonsense Mutation 5, Frame Shift Ins 3, Splice Site 2, Frame Shift Del 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANTXR2 | c.1073dup p.A359Cfs*13 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | catalogued as rs312262690; ClinVar: pathogenic; called by pindel, varscan2
- AC136428.1 | c.112A>G p.R38G | Missense Mutation (SNP) | VAF 132/391 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV71169304; called by muse, mutect2, varscan2
- ANO8 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.109); catalogued as COSV99344105; called by muse, varscan2
- ARID2 | c.2225C>T p.S742F | Missense Mutation (SNP) | VAF 151/322 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV57616234; called by muse, mutect2, varscan2
- ATG9A | c.1635C>A p.Y545* | Nonsense Mutation (SNP) | VAF 13/126 reads (10%) | catalogued as COSV99521583; called by muse, mutect2
- BOD1 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV53633370; called by muse, mutect2, varscan2
- CCDC180 | c.1248+1G>C p.X416_splice | Splice Site (SNP) | VAF 16/72 reads (22%) | catalogued as COSV63836183; called by muse, varscan2
- CDK15 | c.781G>A p.V261M (on ENST00000652192 / NM_001366386.2; = p.V210M on NM_139158.2) | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755877050, COSV53636913, COSV53637977; called by muse, mutect2, varscan2
- CDYL | c.1392G>A p.W464* (on ENST00000328908 / NM_001368125.1; = p.W410* on NM_004824.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/244 reads (5%) | catalogued as COSV100188801; called by muse, mutect2
- CELF4 | c.86G>C p.S29T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58446890, COSV58467921; called by muse, mutect2, varscan2
- CREBZF | c.815C>A p.A272D | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99476124; called by muse, mutect2
- DMXL2 | c.2345T>C p.F782S | Missense Mutation (SNP) | VAF 59/337 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51857778; called by muse, mutect2, varscan2
- DNAH2 | c.7117C>G p.L2373V | Missense Mutation (SNP) | VAF 70/461 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.171); catalogued as COSV66728389; called by muse, mutect2, varscan2
- DOCK3 | c.3554C>A p.T1185N | Missense Mutation (SNP) | VAF 176/263 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0.334); catalogued as COSV56553577; called by muse, mutect2, varscan2
- DUSP1 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53321312; called by muse, mutect2
- EOMES | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 120/181 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1473312287, COSV55416020; called by muse, mutect2, varscan2
- EVPL | c.5829dup p.L1944Afs*23 | Frame Shift Ins (INS) | VAF 5/32 reads (16%) | catalogued as rs756303950; called by mutect2, pindel, varscan2
- FLG | c.9454T>A p.S3152T | Missense Mutation (SNP) | VAF 66/455 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.044); catalogued as COSV100910619; called by muse, mutect2, varscan2
- GRIA4 | c.1151C>A p.P384H | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.091); catalogued as COSV56922885; called by muse, mutect2, varscan2
- IL12RB2 | c.757C>A p.L253M | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV52027931; called by muse, mutect2, varscan2
- INPPL1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs774794017, COSV53352894; called by muse, mutect2, varscan2
- ITGA8 | c.484A>G p.T162A | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV65237249; called by muse, mutect2, varscan2
- KCNH2 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.05); catalogued as COSV100059256; called by muse, mutect2, varscan2
- KIAA1210 | c.1694G>A p.G565D | Missense Mutation (SNP) | VAF 157/374 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV68180629, COSV68181153; called by muse, mutect2, varscan2
- LRP1B | c.8809G>A p.G2937R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67275037, COSV67281194; called by muse, mutect2
- LRP2 | c.9128G>A p.R3043H | Missense Mutation (SNP) | VAF 63/277 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.276); catalogued as rs143078432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NGEF | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV50921135, COSV50963847; called by muse, mutect2, varscan2
- NLRP13 | c.206C>A p.S69Y | Missense Mutation (SNP) | VAF 20/491 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as COSV100738055; called by muse, mutect2
- OLFM3 | c.454G>C p.E152Q (on ENST00000338858 / NM_001288821.1; = p.E132Q on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.132); catalogued as COSV58805324; called by muse, mutect2
- OR2T6 | c.164T>C p.L55P | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63217159; called by muse, mutect2, varscan2
- PADI1 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 44/372 reads (12%) | catalogued as COSV64937799; called by muse, varscan2
- PCDHGA5 | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | catalogued as rs561614642, COSV53977221; called by mutect2, varscan2
- RAB3C | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 69/430 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV51443194; called by muse, mutect2, varscan2
- RREB1 | c.4615C>G p.P1539A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58566807; called by muse, mutect2, varscan2
- SCN3A | c.2156T>A p.L719H | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51826623; called by muse, mutect2, varscan2
- SEZ6L | c.2212+1G>A p.X738_splice | Splice Site (SNP) | VAF 118/255 reads (46%) | catalogued as COSV50683612; called by muse, mutect2, varscan2
- SLC24A2 | c.1544A>C p.Y515S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53877611; called by muse, mutect2, varscan2
- SLC26A6 | c.1783_1785del p.E595del | In Frame Del (DEL) | VAF 42/215 reads (20%) | catalogued as rs780427143; called by pindel, varscan2
- SNX29 | c.370A>G p.N124D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV73754504; called by muse, mutect2, varscan2
- SOCS5 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 48/247 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV60603916, COSV60604974; called by muse, mutect2, varscan2
- SUPT5H | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV63242533; called by muse, mutect2, varscan2
- TAF1 | c.1817G>A p.G606D (on ENST00000373790 / NM_138923.4; = p.G627D on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52127308; called by muse, mutect2, varscan2
- TIAM1 | c.1627C>T p.H543Y | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99733111; called by muse, mutect2
- TP53 | c.625_629del p.R209Hfs*5 | Frame Shift Del (DEL) | VAF 148/208 reads (71%) | catalogued as COSV53718936; called by mutect2, pindel, varscan2
- TTN | c.8923C>G p.L2975V (on ENST00000591111; = p.L2929V on NM_003319.4) | Missense Mutation (SNP) | VAF 31/124 reads (25%) | PolyPhen possibly damaging (0.814); catalogued as COSV100630695, COSV60391208; called by muse, mutect2, varscan2
- TYW3 | c.226A>G p.T76A | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as COSV61718870; called by muse, mutect2, varscan2
- UBAP2 | c.2159C>T p.S720L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs144480091; called by muse, mutect2, varscan2
- ZBTB20 | c.1507G>T p.A503S (on ENST00000474710 / NM_001164342.2; = p.A430S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV61872464; called by muse, mutect2, varscan2
- ZBTB22 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as COSV56473339; called by muse, mutect2, varscan2
- CKAP2L | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.055); called by muse, mutect2
- EPB42 | c.853C>T p.P285S (on ENST00000441366 / NM_001114134.2; = p.P315S on NM_000119.3) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIA3 | c.253del p.S85Pfs*2 | Frame Shift Del (DEL) | VAF 92/199 reads (46%) | called by mutect2, pindel, varscan2
- MET | c.3622A>G p.R1208G | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYO6 | c.2800G>A p.E934K | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.158); called by muse, mutect2
- PPP1R12C | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2
- PRR5L | c.265_266insAAAG p.L89Qfs*30 | Frame Shift Ins (INS) | VAF 18/412 reads (4%) | called by muse*, mutect2
- AGRN | c.252C>T p.S84= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV101038617; called by muse, mutect2
- ANKRD6 | c.1431G>T p.L477= | Silent (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- B3GALT4 | c.651G>A p.L217= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV101005557; called by mutect2, varscan2
- CAPN12 | c.126G>A p.S42= | Silent (SNP) | VAF 20/277 reads (7%) | catalogued as rs199675482, COSV61015434; called by muse, mutect2
- CD99L2 | c.363G>A p.L121= | Silent (SNP) | VAF 51/247 reads (21%) | catalogued as COSV100692012; called by muse, mutect2, varscan2
- CEP250 | c.3873G>A p.Q1291= | Silent (SNP) | VAF 58/585 reads (10%) | catalogued as COSV100698764; called by muse, mutect2
- CHST15 | c.909G>A p.G303= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs1463244014, COSV100654945; called by muse, mutect2, varscan2
- CLIP1 | c.2481G>T p.G827= (on ENST00000620786 / NM_001247997.1; = p.G816= on NM_002956.2) | Silent (SNP) | VAF 66/307 reads (21%) | catalogued as rs772841127, COSV56809562; called by muse, mutect2, varscan2
- CSMD1 | c.1620G>C p.T540= (on ENST00000520002; = p.T539= on NM_033225.6) | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs185713105, COSV59393584; called by muse, mutect2, varscan2
- DPYD | c.1386A>C p.P462= | Silent (SNP) | VAF 36/199 reads (18%) | catalogued as COSV64595011, COSV64596911, COSV64617212; called by muse, mutect2, varscan2
- DSCAML1 | c.525C>T p.P175= (on ENST00000321322; = p.P115= on NM_020693.4) | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV100354803; called by muse, mutect2
- GIMAP8 | c.1677C>T p.Y559= | Silent (SNP) | VAF 34/345 reads (10%) | catalogued as COSV56231721; called by muse, mutect2
- GSTA2 | c.216C>G p.L72= | Silent (SNP) | VAF 88/954 reads (9%) | catalogued as COSV101534030; called by muse, mutect2
- HEATR9 | c.1158G>A p.V386= | Silent (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2
- IL13RA2 | c.582T>C p.N194= | Silent (SNP) | VAF 56/154 reads (36%) | catalogued as COSV54567886; called by muse, mutect2, varscan2
- INTS4 | c.552C>G p.V184= | Silent (SNP) | VAF 72/326 reads (22%) | catalogued as COSV71093131, COSV71093705; called by muse, mutect2, varscan2
- KIF22 | c.369G>A p.V123= | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- MAGEB1 | c.717G>T p.G239= | Silent (SNP) | VAF 16/214 reads (7%) | catalogued as rs1305138383, COSV100974856; called by muse, mutect2
- MYH1 | c.4482A>G p.E1494= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV56858298; called by muse, mutect2, varscan2
- NADK2 | c.684G>A p.G228= (on ENST00000381937 / NM_001085411.3; = p.G65= on NM_153013.4) | Silent (SNP) | VAF 38/161 reads (24%) | catalogued as COSV56939902; called by muse, mutect2, varscan2
- PPARGC1A | c.1923G>A p.Q641= | Silent (SNP) | VAF 24/461 reads (5%) | catalogued as COSV99337307; called by muse, mutect2
- PREP | c.1248C>T p.P416= (on ENST00000369110; = p.P482= on NM_002726.5) | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as COSV64872549; called by muse, mutect2, varscan2
- RRBP1 | c.3219A>G p.E1073= (on ENST00000377813 / NM_001365613.2; = p.E640= on NM_004587.3) | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs1235147969, COSV55709539; called by muse, mutect2, varscan2
- SCN2A | c.1242C>T p.F414= | Silent (SNP) | VAF 8/231 reads (3%) | called by muse, mutect2
- SCN8A | c.2676G>A p.V892= | Silent (SNP) | VAF 15/218 reads (7%) | catalogued as COSV100633345, COSV61984732; called by muse, mutect2
- SYT9 | c.1209G>T p.L403= | Silent (SNP) | VAF 33/354 reads (9%) | catalogued as COSV59626122; called by muse, mutect2
- TBR1 | c.462C>T p.N154= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as rs778312516, COSV67419407; called by muse, mutect2, varscan2
- TEAD2 | c.249C>T p.I83= | Silent (SNP) | VAF 21/173 reads (12%) | catalogued as rs746445822, COSV55563278; called by muse, mutect2, varscan2
- TIGD4 | c.477G>A p.S159= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as rs141579935; called by muse, mutect2, varscan2
- TUBB | c.420C>T p.G140= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as rs773923877, COSV58357535; called by muse, mutect2, varscan2
- USP31 | c.3294G>A p.E1098= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV54858163; called by muse, mutect2, varscan2
- Z83844.2 | c.1590C>T p.C530= | Silent (SNP) | VAF 53/105 reads (50%) | catalogued as COSV53217613; called by muse, mutect2, varscan2
- ZBTB32 | c.702C>T p.P234= | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2
- ZNF445 | c.2826G>A p.Q942= | Silent (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- CIT | c.2082+1912G>A | Intron (SNP) | VAF 99/241 reads (41%) | catalogued as rs762975110, COSV55866306; called by muse, mutect2, varscan2
